Gene-level copy-number profile of tumor specimen HTMCP-03-06-02344-01A from CGCI case HTMCP-03-06-02344, project CGCI-HTMCP-CC (HIV+ Tumor Molecular Characterization Project - Cervical Cancer). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, keratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIIB; Tumor grade: G1; Age at diagnosis: 46.5 years (17,001 days).
Specimen HTMCP-03-06-02344-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file df6a7910-8f98-4908-bc4e-d84c9e723935.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HTMCP-03-06-02344-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,229 have no estimate.
https://portal.gdc.cancer.gov/files/2ec6c7db-4d7f-4d6f-a523-404876d6dcd0

Most common (modal) total copy number across autosomal genes: 6 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 6; copy number 1: 5; copy number 2: 497; copy number 3: 275; copy number 4: 22,300; copy number 5: 4,209; copy number 6: 27,487; copy number 7: 277; copy number 8: 229; copy number 9: 229; copy number 10: 452; copy number 11: 137; copy number 12: 82; copy number 13: 727; copy number 14: 597; copy number 15: 781; copy number 16: 33; copy number 17: 50; copy number 18: 14; copy number 21: 2; copy number 28: 5.

Homozygous deletions (total copy number 0; autosomes only): 6 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:41,890,314–42,189,887, 5 genes (within-gene range 0–3): CNTNAP3B, RBM17P3, CR788268.1, RN7SL343P, SPATA31A6.
- chr11:25,588,475–25,588,795, 1 gene: RPL36AP40.

Amplified relative to the modal value (total copy number ≥ 13, i.e. more than twice the modal value of 6; autosomes only): 1,198 genes in 13 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:165,469,647–165,953,816, 6 genes, copy number 18 (within-gene range 12–18): CSRNP3, GALNT3, AC009495.3, AC009495.1, AC009495.2, TTC21B.
- chr2:171,317,405–177,618,742, 140 genes, copy number 13–16 (broad region; genes not listed).
- chr3:148,279,682–198,123,232, 878 genes, copy number 13–17 (within-gene range 12–17) (broad region; genes not listed).
- chr5:40,998,017–41,071,342, 1 gene, copy number 14: MROH2B.
- chr5:41,585,882–43,525,310, 47 genes, copy number 14: AC008817.1, OXCT1, AC034222.2, OXCT1-AS1, AC034222.1, C5orf51, FBXO4, RPSAP38, Y_RNA, MTHFD2P6, AC108099.1, GHR, SERBP1P6, AC093225.1, AC113368.1, CCDC152, SELENOP, AC008945.1, AC008945.2, PPIAP77, PRELID3BP4, PRELID3BP5, PRELID3BP6, PRELID3BP7, AC008875.1, AC025171.1, AC025171.3, AC025171.5, ANXA2R, AC025171.2, AC025171.4, ZNF131, AC106800.3, NIM1K, AC106800.1, AC106800.2, TUBAP14, HMGCS1, AC114947.2, AC114947.1, CCL28, TMEM267, AC114956.2, C5orf34, EEF1A1P19, C5orf34-AS1, AC114956.1.
- chr7:38,239,580–38,249,572, 1 gene, copy number 14: TRGC2.
- chr7:38,257,879–38,330,935, 12 genes, copy number 14: TRGC1, TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1, TRGV9, TRGVA, AC006033.2, TRGV8.
- chr14:22,147,995–22,502,292, 54 genes, copy number 14: TRAV27, TRAV28, TRAV29DV5, TRAV30, TRAV31, TRAV32, TRAV33, AC244502.1, TRAV26-2, TRAV34, TRAV35, TRAV36DV7, TRAV37, TRAV38-1, TRAV38-2DV8, TRAV39, TRAV40, TRAV41, AC244502.2, AC244502.3, TRDV2, TRDD1, TRDD2, TRDD3, TRDJ1, TRDJ4, TRDJ2, TRDJ3, TRDC, TRDV3, TRAJ61, TRAJ60, TRAJ59, TRAJ58, TRAJ57, TRAJ56, TRAJ55, TRAJ54, TRAJ53, TRAJ52, TRAJ51, TRAJ50, TRAJ49, TRAJ48, TRAJ47, TRAJ46, TRAJ45, TRAJ44, TRAJ43, TRAJ42, TRAJ41, TRAJ40, TRAJ39, TRAJ38.
- chr14:22,547,506–22,552,156, 1 gene, copy number 14: TRAC.
- chr21:19,046,310–21,615,437, 22 genes, copy number 13–28: AP000431.2, AP000431.1, SLC6A6P1, AP000855.1, RNU1-139P, RPL37P4, NIPA2P3, SREK1IP1P1, C1QBPP1, LINC01683, LINC02573, RNU6-772P, RN7SKP147, FDPSP6, KRT18P2, RPS3AP1, AP001506.1, LINC00320, PPIAP1, NCAM2, AP001136.1, AP001117.1.
- chr21:25,169,431–26,845,409, 29 genes, copy number 14–18 (within-gene range 14–28): AP001341.1, RNA5SP489, RPL13AP7, AP001340.1, LINC00158, AP000221.1, MIR155HG, MIR155, AP000223.1, MRPL39, JAM2, RNGTTP1, AP000224.1, FDX1P2, ATP5PF, GABPA, LLPHP2, APP, AP001442.1, RNU6-123P, AP001439.1, AP000229.1, RNU6-926P, AP001595.1, AP001596.1, CYYR1-AS1, AP001596.2, CYYR1, ADAMTS1.
- chr21:27,143,344–27,492,261, 6 genes, copy number 13: GPX1P2, AP001605.1, AP001604.1, EIF4A1P1, RPL10P1, NCSTNP1.
- chr21:27,722,379–27,751,233, 1 gene, copy number 15: LINC00113.

Autosomal genes at a single copy (total copy number 1): 5. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
